Somatic mutation profile of tumor specimen MMRF_2853_1_BM_CD138pos (aliquot MMRF_2853_1_BM_CD138pos_T1_KHS5U_L16586) from MMRF case MMRF_2853, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2853_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32556ec6-f27e-4373-b882-89a9e49d8d77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2853_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2853_1_PB_WBC_C2_KHS5U_L16676; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/389955bb-6a93-4323-88f1-87a8ba25127a

The open-access MAF lists 149 somatic variants for this specimen: 56 protein-altering or splice-affecting, 19 silent, 74 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 44, Silent 19, Intron 14, 5'UTR 9, 5'Flank 4, Frame Shift Del 3, RNA 3, Splice Site 2, Nonsense Mutation 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR1B15 | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV71151070; called by muse, mutect2, varscan2
- ATN1 | c.1509_1511del p.H504del | In Frame Del (DEL) | VAF 5/45 reads (11%) | catalogued as rs1555143796; called by mutect2*, varscan2
- BUD13 | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 17/135 reads (13%) | catalogued as rs1263089957, COSV52767561; called by muse, mutect2, varscan2
- CA5B | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs957425532; called by muse, mutect2, varscan2
- COL19A1 | c.2096G>T p.C699F | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100505352; called by muse, mutect2, varscan2
- DCAF12L1 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 86/154 reads (56%) | catalogued as COSV64422545; called by muse, mutect2, varscan2
- EPB41L4A | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs562929678, COSV54865021, COSV54866254; called by muse, mutect2, varscan2
- EPHB2 | c.2530C>T p.R844W (on ENST00000400191 / NM_001309193.2; = p.R845W on NM_004442.7) | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs55826626, COSV101007136; called by muse, mutect2, varscan2
- F10 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD1510717, CM063967; called by muse, mutect2, varscan2
- FAM120B | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs1197721716; called by muse, mutect2, varscan2
- IGHV2-70 | c.288A>T p.K96N | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as rs531218949; called by muse, varscan2
- IGHV2-70 | c.96A>T p.K32N | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368957766; called by muse, varscan2
- LRRC7 | c.3175del p.A1059Lfs*3 (on ENST00000651989 / NM_001370785.2; = p.A1026Lfs*3 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 53/133 reads (40%) | catalogued as COSV50539467; called by mutect2, pindel, varscan2
- MEGF6 | c.4214G>A p.R1405Q | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs567237600; called by muse, mutect2, varscan2
- MYOF | c.6065G>A p.R2022H | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs754851421, COSV63711614; called by muse, mutect2, varscan2
- NEK4 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs200701452; called by muse, mutect2, varscan2
- RNASEH2B | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs1318688817; called by muse, mutect2, varscan2
- SLCO2B1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs543049597, COSV56935587; called by muse, mutect2, varscan2
- SON | c.3370A>G p.M1124V | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as rs375095792; called by muse, mutect2, varscan2
- SPATA5L1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.173); catalogued as COSV59745510; called by muse, mutect2, varscan2
- SYNM | c.4478C>T p.A1493V (on ENST00000336292 / NM_145728.3; = p.A1181V on NM_015286.6) | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs372660853; called by muse, mutect2, varscan2
- TBC1D12 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs368922760; called by muse, mutect2, varscan2
- TBX2 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.212); catalogued as rs1466303780; called by muse, mutect2
- WRAP73 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 14/411 reads (3%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54563942; called by muse, mutect2
- AMN | c.147G>C p.E49D | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ARHGEF28 | c.4517G>A p.R1506Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- CDK3 | c.117-7C>T | Splice Region (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- CYP17A1 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- DOCK6 | c.4763G>T p.G1588V | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- DTNBP1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- EIF4A2 | c.547_553del p.D183Qfs*5 | Frame Shift Del (DEL) | VAF 8/10 reads (80%) | called by mutect2, varscan2
- ELMOD1 | c.163+2T>C p.X55_splice | Splice Site (SNP) | VAF 94/260 reads (36%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.166); called by muse, varscan2
- IGKV2-24 | c.64A>C p.I22L | Missense Mutation (SNP) | VAF 131/216 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- IGSF9 | c.2314C>T p.R772C (on ENST00000368094 / NM_001135050.2; = p.R756C on NM_020789.4) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2
- ITPR2 | c.7442C>A p.T2481N | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KIF17 | c.1712C>T p.S571F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.146); called by mutect2, varscan2
- MEX3D | c.865G>C p.V289L | Missense Mutation (SNP) | VAF 49/260 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.537del p.W180Gfs*8 | Frame Shift Del (DEL) | VAF 17/133 reads (13%) | called by mutect2, pindel, varscan2
- MYO1A | c.1669C>T p.L557F | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- NR2F2 | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 97/389 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- OR1S2 | c.962A>C p.K321T | Missense Mutation (SNP) | VAF 134/424 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- OR8G5 | c.648C>A p.S216R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- PLEKHA4 | c.2070G>A p.M690I | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN22 | c.335A>T p.D112V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASGRF2 | c.501A>C p.Q167H | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RUSC2 | c.4226G>C p.W1409S | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SEMA5A | c.52A>G p.R18G | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMC3 | c.379A>G p.S127G | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- SUSD6 | c.271A>T p.N91Y | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TAOK2 | c.3019T>C p.C1007R | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMED1 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TWIST2 | c.394A>T p.S132C | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- UNC13C | c.5449G>A p.G1817R | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- XYLB | c.1120+1G>A p.X374_splice | Splice Site (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- ZNF286A | c.1043A>C p.H348P | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCAS3 | c.2589C>T p.A863= (on ENST00000390652 / NM_001353144.2; = p.A848= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/111 reads (32%) | catalogued as rs564865113, COSV66778509; called by muse, mutect2, varscan2
- BRD1 | c.2218C>A p.R740= | Silent (SNP) | VAF 33/62 reads (53%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.4752C>T p.N1584= | Silent (SNP) | VAF 60/202 reads (30%) | catalogued as COSV56718303; called by muse, mutect2, varscan2
- CCDC87 | c.1149G>A p.G383= | Silent (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- CDCP1 | c.21G>C p.G7= | Silent (SNP) | VAF 19/278 reads (7%) | called by muse, mutect2
- DCAF12L1 | c.741G>C p.P247= | Silent (SNP) | VAF 86/181 reads (48%) | catalogued as COSV64422058; called by muse, mutect2, varscan2
- DNAH17 | c.2916G>T p.L972= | Silent (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- FGF20 | c.576T>C p.P192= | Silent (SNP) | VAF 92/196 reads (47%) | called by muse, mutect2, varscan2
- GCN1 | c.4056C>T p.S1352= | Silent (SNP) | VAF 20/21 reads (95%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.264G>A p.T88= | Silent (SNP) | VAF 54/68 reads (79%) | catalogued as rs1429542253; called by muse, varscan2
- IGHV4-34 | c.150C>T p.V50= | Silent (SNP) | VAF 75/146 reads (51%) | catalogued as rs587738411; called by muse, mutect2, varscan2
- IGKV2-24 | c.348T>C p.A116= | Silent (SNP) | VAF 50/166 reads (30%) | catalogued as rs532474654; called by muse, mutect2, varscan2
- LRFN2 | c.57C>T p.D19= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as rs147133948; called by muse, mutect2, varscan2
- MRPL36 | c.207G>A p.K69= | Silent (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- PIAS1 | c.792C>T p.N264= | Silent (SNP) | VAF 134/346 reads (39%) | called by muse, mutect2, varscan2
- POLR3A | c.4068A>T p.G1356= | Silent (SNP) | VAF 68/142 reads (48%) | called by muse, mutect2, varscan2
- SYNGR3 | c.504G>A p.L168= | Silent (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- WNT7A | c.30C>T p.G10= | Silent (SNP) | VAF 71/192 reads (37%) | called by muse, mutect2, varscan2
- ZNF556 | c.576G>A p.T192= | Silent (SNP) | VAF 25/359 reads (7%) | catalogued as rs201103084; called by muse, mutect2
- ADRB1 | c.*156G>C | 3'UTR (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- AMOT | c.*2479C>A | 3'UTR (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- AMOT | c.*2237C>G | 3'UTR (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- ARRDC3 | c.*1233G>A | 3'UTR (SNP) | VAF 11/80 reads (14%) | catalogued as rs1276967942; called by muse, mutect2, varscan2
- ASPH | c.*648dup | 3'UTR (INS) | VAF 16/35 reads (46%) | catalogued as rs539387497; called by mutect2, varscan2
- C9orf163 | n.2082G>A | RNA (SNP) | VAF 83/277 reads (30%) | called by muse, mutect2, varscan2
- CAT | c.*91C>T | 3'UTR (SNP) | VAF 49/177 reads (28%) | called by muse, mutect2, varscan2
- COA8 | c.123+230A>T | Intron (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- DDR1 | c.566-79G>A | Intron (SNP) | VAF 3/35 reads (9%) | catalogued as rs1221526116; called by muse, mutect2
- DLG3 | c.*1068C>T | 3'UTR (SNP) | VAF 77/96 reads (80%) | called by muse, varscan2
- DLG3 | c.*1400_*1401del | 3'UTR (DEL) | VAF 28/52 reads (54%) | called by mutect2, pindel, varscan2
- DLG3 | c.*1663C>G | 3'UTR (SNP) | VAF 104/140 reads (74%) | called by muse, varscan2
- DLG3 | c.*1755C>T | 3'UTR (SNP) | VAF 127/174 reads (73%) | called by muse, varscan2
- DLG3 | c.*2053_*2056delinsTA | 3'UTR (DEL) | VAF 35/55 reads (64%) | called by pindel, varscan2*
- DLG3 | c.*2107C>G | 3'UTR (SNP) | VAF 37/56 reads (66%) | called by muse, varscan2
- DPP10 | c.*1731A>G | 3'UTR (SNP) | VAF 35/50 reads (70%) | called by muse, mutect2, varscan2
- DTWD2 | c.-27T>C | 5'UTR (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- EED | c.727-826C>A | Intron (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- FER | c.*960_*961dup | 3'UTR (INS) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- GAB1 | c.-5G>T | 5'UTR (SNP) | VAF 20/196 reads (10%) | called by muse, mutect2, varscan2
- GDAP1L1 | c.*833C>T | 3'UTR (SNP) | VAF 70/142 reads (49%) | called by muse, mutect2, varscan2
- GGPS1 | c.*54T>G | 3'UTR (SNP) | VAF 61/247 reads (25%) | catalogued as COSV99270381; called by muse, mutect2, varscan2
- GNAI1 | c.*267A>C | 3'UTR (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- GRIK3 | c.*3976C>T | 3'UTR (SNP) | VAF 59/132 reads (45%) | catalogued as rs1223918350; called by muse, mutect2, varscan2
- H2AX | c.-12T>G | 5'UTR (SNP) | VAF 143/398 reads (36%) | called by muse, mutect2, varscan2
- HNRNPAB | c.-220G>A | 5'UTR (SNP) | VAF 42/63 reads (67%) | called by muse, mutect2, varscan2
- HOXD8 | c.-509C>T | 5'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- HS6ST1 | c.*1078C>T | 3'UTR (SNP) | VAF 63/101 reads (62%) | called by muse, mutect2, varscan2
- HSPE1 | c.3+17C>T | Intron (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- IGF1R | c.*623C>T | 3'UTR (SNP) | VAF 23/103 reads (22%) | catalogued as rs565525294; called by muse, mutect2, varscan2
- IL26 | c.*292G>A | 3'UTR (SNP) | VAF 25/72 reads (35%) | catalogued as rs963296216; called by muse, mutect2, varscan2
- IREB2 | c.1023+230T>C | Intron (SNP) | VAF 39/182 reads (21%) | catalogued as rs139614134; called by muse, mutect2, varscan2
- KAT6A | c.*763A>C | 3'UTR (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2
- KCNMB1 | c.-6G>T | 5'UTR (SNP) | VAF 27/233 reads (12%) | called by muse, mutect2, varscan2
- LACRT | c.253+139A>T | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- LINC00637 | n.933T>C | RNA (SNP) | VAF 41/75 reads (55%) | called by muse, mutect2, varscan2
- LTB | c.162+46T>C | Intron (SNP) | VAF 55/97 reads (57%) | called by muse, mutect2, varscan2
- MAGI2 | c.*422C>T | 3'UTR (SNP) | VAF 9/45 reads (20%) | catalogued as rs183077586; called by muse, mutect2, varscan2
- MCTP2 | c.*608G>A | 3'UTR (SNP) | VAF 38/81 reads (47%) | catalogued as rs557113362; called by muse, mutect2, varscan2
- MEMO1 | c.213-2777T>C | Intron (SNP) | VAF 148/230 reads (64%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851229 A>T | 5'Flank (SNP) | VAF 74/156 reads (47%) | catalogued as rs578215375; called by muse, varscan2
- MS4A14 | chr11:60396091 C>T | 5'Flank (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- MYO1E | c.-2C>G | 5'UTR (SNP) | VAF 30/57 reads (53%) | catalogued as rs573448797, COSV55686570; called by muse, mutect2
- NETO1 | c.-545C>T | 5'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- NFIB | c.*2329T>A | 3'UTR (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- PARL | c.*5G>A | 3'UTR (SNP) | VAF 18/48 reads (38%) | catalogued as rs1383986629; called by muse, mutect2, varscan2
- PCK1 | c.*336dup | 3'UTR (INS) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- PCSK5 | c.*527C>A | 3'UTR (SNP) | VAF 10/19 reads (53%) | called by muse, varscan2
- PIK3R5 | c.*875T>A | 3'UTR (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- PPAT | c.*1598C>T | 3'UTR (SNP) | VAF 46/137 reads (34%) | called by muse, mutect2, varscan2
- PPME1 | c.*953C>T | 3'UTR (SNP) | VAF 74/187 reads (40%) | called by muse, mutect2, varscan2
- PTGS2 | c.*681G>C | 3'UTR (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- PYGO1 | c.*968C>T | 3'UTR (SNP) | VAF 30/103 reads (29%) | called by muse, mutect2, varscan2
- RASSF6 | c.*1492_*1495del | 3'UTR (DEL) | VAF 23/56 reads (41%) | catalogued as rs1374732427; called by mutect2, pindel, varscan2
- RDX | c.1748+2075_1748+2078del | Intron (DEL) | VAF 80/553 reads (14%) | called by mutect2, pindel, varscan2
- RFNG | c.317-52C>T | Intron (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- RUSC2 | c.*309G>A | 3'UTR (SNP) | VAF 24/137 reads (18%) | called by muse, mutect2, varscan2
- RUSC2 | c.*495A>T | 3'UTR (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- SDR16C6P | n.47A>G | RNA (SNP) | VAF 3/43 reads (7%) | catalogued as rs1002754091; called by muse, mutect2
- SECISBP2L | c.*400T>C | 3'UTR (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- SKI | c.*1785G>T | 3'UTR (SNP) | VAF 29/206 reads (14%) | called by muse, mutect2, varscan2
- SLC25A27 | c.*234C>T | 3'UTR (SNP) | VAF 52/366 reads (14%) | called by muse, mutect2, varscan2
- SLC2A12 | c.*2320C>G | 3'UTR (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- SSR1 | c.*3207G>T | 3'UTR (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- TENT5A | c.*1208T>G | 3'UTR (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- TNRC18 | chr7:5427593 G>A | 5'Flank (SNP) | VAF 73/180 reads (41%) | catalogued as rs763299330; called by muse, mutect2, varscan2
- TRPV5 | c.1122+75C>T | Intron (SNP) | VAF 15/91 reads (16%) | catalogued as COSV99520180; called by muse, mutect2, varscan2
- UBR3 | c.*456T>C | 3'UTR (SNP) | VAF 38/84 reads (45%) | called by muse, mutect2, varscan2
- USH2A | c.4627+227A>G | Intron (SNP) | VAF 27/123 reads (22%) | called by muse, mutect2, varscan2
- WDR45B | c.*695C>T | 3'UTR (SNP) | VAF 77/224 reads (34%) | called by muse, mutect2, varscan2
- WWC2 | chr4:183098368 G>A | 5'Flank (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2
- XKR5 | c.242+3475G>C | Intron (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2
- ZIC2 | c.-46C>T | 5'UTR (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- ZIK1 | c.33+100G>A | Intron (SNP) | VAF 47/157 reads (30%) | called by muse, mutect2, varscan2
